Somatic mutation profile of tumor specimen 0DLSYD from CCDI case PBBZKJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.8 years (6,504 days).
Specimen 0DLSYD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f1b37b91-db4b-4a29-b195-4fb7170cc192.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLSX8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6070266c-d103-4ffd-a70c-2d62d1312e4c

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TG | c.2936G>A p.R979Q | Missense Mutation (SNP) | VAF 122/363 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs143609789, COSV55091409; called by muse, mutect2, varscan2
- ARX | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 26/834 reads (3%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.018); called by muse, mutect2
- OBSCN | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 20/732 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.41); called by muse, mutect2
- CLRN3 | c.159C>T p.Y53= | Silent (SNP) | VAF 211/599 reads (35%) | catalogued as rs777423555, COSV100899726, COSV64098577; called by muse, mutect2, varscan2
- PTCRA | c.246G>A p.T82= | Silent (SNP) | VAF 102/274 reads (37%) | catalogued as rs760873532; called by muse, mutect2, varscan2
- TIGD5 | c.48C>T p.R16= | Silent (SNP) | VAF 74/242 reads (31%) | called by muse, mutect2, varscan2
